Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A3U5, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A3U5-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient:

[REDACTED]

:37

CC:

Patient Address: [REDACTED]

....

Clinical Diagnosis & History:

Retroperitoneal sarcoma, no biopsy performed.

Specimens Submitted:

1: Radical resection of right retroperitoneal sarcoma with right hemicolectomy

DIAGNOSIS:

1. Retroperitoneal mass and portion of right colon, radical resection and right hemicolectomy:

- Dedifferentiated Liposarcoma arising in background of well-differentiated liposarcoma.
- The tumor measures 10.6 cm in greatest dimension.
- Dedifferentiated component is high-grade spindle cell sarcoma.
- Separate nodules of well-differentiated liposarcoma (largest nodule - 1.5 cm).
- The tumor shows foci of necrosis (40% of tumor).
- Well-differentiated liposarcoma component extends to the resection margin.
- Foci suspicious for vascular invasion.
- Benign portion of terminal ileum, appendix and colon.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	RECUT	
	RECUT	

Gross Description:

** Continued on next page **

ICD-O-3
liposarcoma, dedifferentiated
8858/3
Site: Retroperitoneum
C48.0

5-2-12 KD

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Accession

----- Page 2 of 2

1). The specimen is received fresh labeled "radical resection of right retroperitoneal sarcoma with right hemicolectomy", and consists of a 10.6 x 9.8 x 9.4 cm, encapsulated, soft tissue mass with an attached portion of right colectomy specimen including a 8 cm in length 3.5 cm in circumference segment of ileum, 7 x 0.5 cm appendix and a 12.5 cm in length and 7.5 cm in maximum circumference colon. Grossly there is no direct tumor extension to the bowel. The mucosa surface of the ileum and colon is tan red and uninvolved by the tumor. The outer surface of soft tissue mass is inked in black. Serial sectioning reveals a tan-yellow pink, soft, smooth and glistening cut surface with multifocal necrosis (necrosis is approximately 40% of the tumor). TPS is performed and photograph is taken. Representative sections are submitted as follows:

Summary of sections:

T - tumor (cassettes 6 to 10 are tumor with capsular margin)
TB - tumor towards bowel (consecutive sections in 2 cassettes)
PM - proximal ileum margin
DM - distal colonic margin
AP - appendix
M - representative mucosa
L - lymph node, bisected

Summary of Sections:

Part 1: Radical resection of right retroperitoneal sarcoma with right hemicolectomy

Block	Sect. Site	PCs
1	AP	2
1	DM	2
2	L	3
1	M	2
1	PM	2
10	T	11
2	TB	3

** End of Report **

Source: NCI Genomic Data Commons file 07d05001-ee5e-4e24-bf3c-6e14a621d4a3 (TCGA-DX-A3U5.BC2CF943-A01D-4BDC-BD11-0AB89A4ED898.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).